Somatic mutation profile of tumor specimen TCGA-RP-A693-06A (aliquot TCGA-RP-A693-06A-13D-A30X-08) from TCGA case TCGA-RP-A693, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.7 years (28,394 days).
Specimen TCGA-RP-A693-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a0e0992-ff70-4a00-ab2d-8733cdb784a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RP-A693-10A (Blood Derived Normal), aliquot TCGA-RP-A693-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/649d2303-49db-4732-8b13-744a6b8b13b0

The open-access MAF lists 934 somatic variants for this specimen: 624 protein-altering or splice-affecting, 299 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 568, Silent 299, Nonsense Mutation 34, Splice Site 10, Splice Region 8, Intron 6, RNA 3, Frame Shift Del 2, 3'Flank 2, In Frame Del 1, In Frame Ins 1.

Variants (750 of 934; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP63 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 28/93 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777174766, COSV59674760; called by muse, mutect2, varscan2
- MAP2K2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504382, COSV53562848; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50744256; called by muse, mutect2, varscan2
- ABCA12 | c.3882G>T p.W1294C (on ENST00000272895 / NM_173076.3; = p.W976C on NM_015657.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM061626, COSV55955454, COSV55975125; called by muse, mutect2, varscan2
- ABCA13 | c.1375T>A p.L459I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV70027436; called by muse, mutect2, varscan2
- AC006059.2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs755531878, COSV59605863; called by muse, mutect2, varscan2
- AC100868.1 | c.1850C>T p.S617F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV51841113, COSV99227187; called by muse, mutect2, varscan2
- ACAN | c.5362G>A p.E1788K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV61359105; called by muse, mutect2, varscan2
- ACAN | c.5995C>T p.P1999S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.219); catalogued as COSV61359112; called by muse, mutect2, varscan2
- ACCSL | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV66580940; called by muse, mutect2, varscan2
- ACSM2B | c.1024C>T p.L342F | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs267604439, COSV61657477; called by muse, mutect2, varscan2
- ACTL6B | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.582); catalogued as COSV50514438; called by muse, mutect2, varscan2
- ADAM7 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.995); catalogued as COSV51538458; called by muse, mutect2
- ADAM9 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV65946638; called by muse, mutect2, varscan2
- ADAMDEC1 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV56474857; called by muse, mutect2, varscan2
- ADAMTS16 | c.2785C>T p.P929S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1392385481, COSV99943616; called by muse, mutect2, varscan2
- ADAMTS16 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV56991319; called by muse, mutect2, varscan2
- ADAMTS20 | c.4669G>A p.E1557K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67130109; called by muse, mutect2, varscan2
- ADCY8 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV53903997; called by mutect2, varscan2
- ADGRF4 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99349227; called by muse, mutect2, varscan2
- ADGRL2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54663095; called by muse, mutect2, varscan2
- ADGRV1 | c.6149G>A p.G2050E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV67983290; called by muse, mutect2, varscan2
- ADH1A | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | catalogued as COSV52924713; called by muse, mutect2, varscan2
- ADHFE1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV52554551; called by muse, mutect2, varscan2
- AFAP1L1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0.068); catalogued as COSV57044803; called by muse, mutect2, varscan2
- AGRN | c.2431C>T p.Q811* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV65069003; called by muse, mutect2, varscan2
- AGRN | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.897); catalogued as rs1361351936, COSV65069009; called by muse, mutect2, varscan2
- AGTRAP | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100065610; called by muse, mutect2
- AK7 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1281525251, COSV50870734; called by muse, mutect2, varscan2
- AKAP1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58469722; called by muse, mutect2, varscan2
- AKAP11 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV50295628; called by muse, mutect2
- AKAP6 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55211127; called by muse, mutect2, varscan2
- ALDH1A1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs1277186462, COSV52790605; called by muse, mutect2, varscan2
- ALOX15B | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs768307447, COSV66479318; called by muse, mutect2, varscan2
- ALPK3 | c.2354A>G p.N785S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV51932400; called by muse, mutect2, varscan2
- AMER3 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1326001866, COSV58466147; called by muse, mutect2
- ANAPC1 | c.3641C>T p.A1214V | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1468407881, COSV61979605; called by muse, mutect2, varscan2
- ANGEL1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs143581712, COSV51872814, COSV99200460; called by muse, mutect2, varscan2
- ANKHD1 | c.4940+1G>A p.X1647_splice | Splice Site (SNP) | VAF 13/60 reads (22%) | catalogued as COSV51845094; called by muse, mutect2, varscan2
- ANKK1 | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.942); catalogued as rs763198483, COSV58271300; called by muse, mutect2, varscan2
- ANKRD22 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV64236324; called by muse, mutect2, varscan2
- ANKRD34A | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1553761184, COSV60160760; called by muse, mutect2
- ANKRD42 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52615458; called by muse, mutect2, varscan2
- ANO3 | c.771G>A p.W257* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as COSV56788100; called by muse, mutect2, varscan2
- AP4E1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs771192552, COSV55916388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APBB1 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 69/326 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV54974629; called by muse, mutect2, varscan2
- ARFGEF3 | c.4132C>T p.P1378S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV52455289; called by muse, mutect2, varscan2
- ARHGAP35 | c.4168C>T p.L1390F | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.201); catalogued as COSV101351926, COSV68330468; called by muse, mutect2, varscan2
- ARID5B | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54418319; called by muse, mutect2, varscan2
- ARRDC4 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51418603; called by muse, mutect2, varscan2
- ART1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as rs758082786, COSV51703903; called by muse, mutect2, varscan2
- ASTN1 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.576); catalogued as COSV56066520; called by muse, mutect2, varscan2
- ATG13 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278335304, COSV56318848, COSV56321238; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2198C>T p.S733F (on ENST00000343619 / NM_001378531.1; = p.S727F on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231803; called by muse, mutect2, varscan2
- ATP8B4 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1272513285, COSV52713506; called by muse, mutect2, varscan2
- AZU1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV52140223; called by muse, mutect2, varscan2
- B4GALNT2 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV55925641; called by muse, mutect2, varscan2
- B4GALNT2 | c.892T>C p.F298L | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55925648; called by muse, mutect2, varscan2
- BAAT | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52288195; called by muse, mutect2
- BAAT | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52288209; called by muse, mutect2, varscan2
- BAP1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1404823823, COSV56236387; ClinVar: uncertain significance; called by muse, mutect2
- BEND4 | c.1231G>T p.G411W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV72469037; called by muse, mutect2, varscan2
- BEND7 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (1); catalogued as rs1338539157, COSV61988376; called by muse, mutect2, varscan2
- BMP3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV51082904; called by muse, mutect2, varscan2
- BRD4 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV54585005; called by muse, mutect2, varscan2
- BRD9 | c.402C>T p.A134= | Splice Region (SNP) | VAF 14/84 reads (17%) | catalogued as rs758667843, COSV51319209, COSV51319691; called by muse, mutect2, varscan2
- BRDT | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV62864436; called by muse, mutect2, varscan2
- C17orf67 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 132/558 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs371206277, COSV67374858; called by muse, mutect2, varscan2
- C22orf23 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50777725; called by muse, mutect2, varscan2
- C2orf16 | c.4911C>G p.S1637R | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100821149; called by muse, mutect2, varscan2
- C2orf16 | c.4912C>T p.H1638Y | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV100821150; called by muse, mutect2, varscan2
- C5 | c.2471T>A p.F824Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV56326294; called by muse, mutect2, varscan2
- CACNA2D2 | c.468G>A p.E156= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56562560; called by muse, mutect2, varscan2
- CACNA2D3 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1213456388, COSV55530236; called by muse, mutect2, varscan2
- CACTIN | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as COSV50267684; called by muse, mutect2, varscan2
- CALR | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs866651711, COSV57122721; called by muse, mutect2
- CAPRIN2 | c.3220C>T p.L1074F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51831964; called by muse, mutect2, varscan2
- CAPSL | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV68437872; called by muse, mutect2, varscan2
- CASP3 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1457645538, COSV57724877; called by muse, mutect2, varscan2
- CCDC146 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53546971; called by muse, mutect2, varscan2
- CCDC180 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1373854027, COSV63829210; called by muse, mutect2, varscan2
- CCDC60 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs759169633, COSV100554485, COSV59542662; called by muse, mutect2, varscan2
- CCDC9 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV55719746; called by muse, mutect2, varscan2
- CCER1 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV62646518; called by muse, mutect2, varscan2
- CD163 | c.2999G>A p.G1000E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866293964, COSV63131495; called by muse, mutect2, varscan2
- CD180 | c.1834T>A p.S612T | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56517629; called by muse, mutect2, varscan2
- CD1C | c.777T>A p.D259E | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63806203; called by muse, mutect2, varscan2
- CDC42BPA | c.4378C>T p.P1460S (on ENST00000334218 / NM_001366019.2; = p.P1447S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV62009075; called by muse, mutect2, varscan2
- CDC7 | c.1331-1G>A p.X444_splice | Splice Site (SNP) | VAF 15/47 reads (32%) | catalogued as COSV52310266; called by muse, mutect2
- CDCA8 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV59238569; called by muse, mutect2, varscan2
- CDH18 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868656497, COSV56901982, COSV56932375, COSV56960090; called by muse, mutect2, varscan2
- CDHR3 | c.2309C>T p.T770I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1479600749, COSV58415836; called by muse, mutect2
- CDK17 | c.1510C>T p.R504* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as rs750936507, COSV54127953; called by muse, mutect2, varscan2
- CDKAL1 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51182167; called by muse, mutect2, varscan2
- CDR2L | c.1180C>T p.R394W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs755427447, COSV61500936; called by muse, mutect2, varscan2
- CDYL2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV73647617; called by muse, mutect2, varscan2
- CEBPE | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as COSV52829585; called by muse, mutect2, varscan2
- CENATAC | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV57722496; called by muse, mutect2, varscan2
- CENPF | c.4930C>T p.Q1644* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as rs1424695409, COSV100871695, COSV100872113; called by muse, mutect2, varscan2
- CENPH | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774650504, COSV51584656; called by muse, mutect2, varscan2
- CEP126 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV54824152; called by muse, mutect2, varscan2
- CEP162 | c.3202G>T p.D1068Y | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57619167; called by muse, varscan2
- CEP44 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.8); catalogued as COSV99639888; called by muse, mutect2, varscan2
- CFAP206 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV51533516; called by muse, mutect2, varscan2
- CFAP54 | c.6326G>A p.R2109K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV61571753; called by muse, mutect2, varscan2
- CFAP58 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV63833705; called by muse, mutect2, varscan2
- CFAP97 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs368433789; called by muse, mutect2
- CFHR5 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV56820729, COSV56823902; called by muse, mutect2, varscan2
- CFI | c.1630G>T p.V544L | Missense Mutation (SNP) | VAF 69/308 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67098364; called by muse, mutect2, varscan2
- CHD8 | c.5725C>T p.R1909W (on ENST00000646647 / NM_001170629.2; = p.R1630W on NM_020920.4) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63036730; called by muse, mutect2, varscan2
- CHML | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV59363636; called by muse, mutect2, varscan2
- CHRM5 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV67247136; called by muse, mutect2, varscan2
- CHST5 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.281); catalogued as COSV60337922; called by muse, mutect2, varscan2
- CHSY3 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV59275982; called by muse, mutect2, varscan2
- CILP2 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99365361; called by muse, mutect2, varscan2
- CLDN18 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV59302390; called by muse, mutect2, varscan2
- CLGN | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs564584207, COSV57774139; called by muse, mutect2, varscan2
- CLIP1 | c.3323C>T p.S1108F (on ENST00000620786 / NM_001247997.1; = p.S1097F on NM_002956.2) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56800568; called by muse, mutect2, varscan2
- CLSTN2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480408352, COSV71720174, COSV71724134; called by muse, mutect2, varscan2
- CLUAP1 | c.495+1G>T p.X165_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV58893343; called by muse, mutect2, varscan2
- CLVS1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs770693777, COSV57970881; called by muse, mutect2, varscan2
- CNKSR3 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV70480947; called by muse, mutect2, varscan2
- CNOT1 | c.6260C>T p.P2087L | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55315225; called by muse, mutect2
- COBL | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV99474685; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL2A1 | c.2699G>A p.G900E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100477901; called by muse, mutect2, varscan2
- COL3A1 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.253); catalogued as COSV58585732; called by muse, mutect2, varscan2
- COL4A5 | c.3185A>T p.K1062I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV60359813; called by muse, mutect2, varscan2
- COL5A2 | c.2218G>A p.D740N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66408818; called by muse, mutect2, varscan2
- COL7A1 | c.7984-1G>A p.X2662_splice | Splice Site (SNP) | VAF 42/149 reads (28%) | catalogued as COSV56476384; called by muse, mutect2, varscan2
- COL7A1 | c.2914G>A p.V972M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.832); catalogued as rs778102512, COSV100098114; called by muse, mutect2, varscan2
- CPED1 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60000425; called by muse, mutect2, varscan2
- CPNE3 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52205629; called by muse, mutect2, varscan2
- CRY2 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101314630; called by muse, mutect2, varscan2
- CRYBB2 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 23/89 reads (26%) | catalogued as COSV68005394; called by muse, mutect2, varscan2
- CRYBB3 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.046); catalogued as rs141617094; called by muse, mutect2, varscan2
- CRYGB | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV53680051; called by muse, mutect2, varscan2
- CSMD2 | c.6595C>T p.P2199S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53902196; called by muse, mutect2, varscan2
- CSMD3 | c.11072G>A p.G3691E (on ENST00000297405 / NM_001363185.1; = p.G3522E on NM_052900.3) | Missense Mutation (SNP) | VAF 82/203 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV52154527; called by muse, mutect2, varscan2
- CSMD3 | c.4306G>A p.D1436N (on ENST00000297405 / NM_001363185.1; = p.D1332N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV52095707, COSV52154546; called by muse, mutect2, varscan2
- CTTN | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57231634; called by muse, mutect2, varscan2
- CYP11B1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52826244; called by muse, mutect2, varscan2
- CYP2A6 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as rs774455621, COSV56534848; called by muse, mutect2, varscan2
- CYP2B6 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57843337; called by muse, mutect2, varscan2
- CYP2R1 | c.650A>T p.N217I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.675); catalogued as COSV58127267; called by muse, mutect2, varscan2
- CYP4B1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV54722954; called by muse, mutect2, varscan2
- DAB1 | c.1694C>T p.S565F (on ENST00000371231; = p.S532F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.909); catalogued as COSV64692273; called by muse, mutect2, varscan2
- DARS2 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV53406488, COSV53408964; called by muse, mutect2, varscan2
- DCAF15 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV54335699; called by muse, mutect2, varscan2
- DDI1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV56374673; called by muse, mutect2, varscan2
- DDX20 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757973800, COSV63830979; called by muse, mutect2, varscan2
- DGKB | c.1610G>A p.G537E | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51775668; called by muse, mutect2
- DHX40 | c.2011C>A p.H671N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV52067037, COSV52069968; called by muse, mutect2, varscan2
- DIO1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59517756; called by muse, mutect2, varscan2
- DLC1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 63/346 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.863); catalogued as rs868602353, COSV52299365; called by muse, mutect2, varscan2
- DMD | c.10490C>T p.S3497F | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV58904405; called by muse, mutect2
- DMWD | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs763208905, COSV52176508; called by muse, mutect2, varscan2
- DMWD | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99353865; called by muse, mutect2, varscan2
- DMXL2 | c.7091C>T p.S2364F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1566998291, COSV51844466; called by muse, mutect2, varscan2
- DNAH10 | c.7263G>A p.M2421I (on ENST00000409039; = p.M2360I on NM_207437.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs537839268, COSV68991769; called by muse, mutect2
- DNAH11 | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60951739; called by muse, varscan2
- DNAH3 | c.6371G>A p.R2124Q | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776382752, COSV54515852; called by muse, mutect2, varscan2
- DNAJC5G | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs151006541; called by muse, mutect2, varscan2
- DOCK3 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56515359, COSV56520534; called by muse, mutect2
- DOCK3 | c.849G>A p.M283I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV56506346; called by muse, mutect2, varscan2
- DPYD | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV60077071; called by muse, mutect2, varscan2
- DSCAML1 | c.4031C>T p.P1344L (on ENST00000321322; = p.P1284L on NM_020693.4) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV58388225; called by muse, mutect2, varscan2
- DSG4 | c.2261G>A p.G754E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs767840706, COSV57390595, COSV57397850; called by muse, mutect2, varscan2
- DTL | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.172); catalogued as COSV100877310; called by muse, mutect2, varscan2
- DTNBP1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV59039310; called by muse, mutect2, varscan2
- E2F8 | c.451+1G>A p.X151_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV51462947; called by muse, mutect2, varscan2
- ECHS1 | c.797C>T p.T266I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV63906744; called by muse, mutect2, varscan2
- EGR3 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57833309; called by muse, mutect2, varscan2
- ELAC2 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52392824; called by muse, mutect2, varscan2
- EML3 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.416); catalogued as rs756695880, COSV53871609; called by muse, mutect2, varscan2
- ENAM | c.405A>C p.Q135H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.465); catalogued as COSV68535730; called by muse, mutect2, varscan2
- ENPP4 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs766472788, COSV58088752; called by muse, mutect2, varscan2
- ENTPD6 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.027); catalogued as rs201669725, COSV61751335; called by muse, mutect2
- EPHA6 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67558967; called by muse, mutect2, varscan2
- EPHA7 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as rs867625037, COSV65181046; called by muse, mutect2, varscan2
- EPHB2 | c.2096C>T p.T699I (on ENST00000400191 / NM_001309193.2; = p.T700I on NM_004442.7) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV101007549, COSV101007583; called by muse, mutect2, varscan2
- EPPK1 | c.6664G>A p.G2222S | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73261064; called by muse, mutect2, varscan2
- EPPK1 | c.4345G>A p.A1449T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV101599998; called by muse, mutect2, varscan2
- ERBB4 | c.2591T>C p.L864P | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61480022; called by muse, mutect2, varscan2
- ERBB4 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.858); catalogued as COSV53522603, COSV53585586; called by muse, mutect2, varscan2
- ERC2 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1248585292, COSV55614936; called by muse, mutect2, varscan2
- ERCC4 | c.2590C>A p.R864S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as COSV61311071, COSV61311618; called by muse, mutect2, varscan2
- ETV7 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV60316746; called by muse, mutect2, varscan2
- EVC | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.125); catalogued as COSV53831544, COSV99381664; called by muse, mutect2, varscan2
- EYA1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58160674; called by muse, mutect2, varscan2
- EYA1 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs750274491, COSV58160693; called by muse, mutect2, varscan2
- F13B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV66373357; called by muse, mutect2, varscan2
- FAM47C | c.2763A>C p.K921N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63725717; called by muse, mutect2, varscan2
- FANCI | c.3060G>A p.E1020= (on ENST00000310775 / NM_001376911.1; = p.E960= on NM_018193.3) | Splice Region (SNP) | VAF 30/126 reads (24%) | catalogued as rs1567173680, COSV55525753; called by muse, mutect2, varscan2
- FASTKD1 | c.177C>G p.N59K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70006808; called by muse, mutect2, varscan2
- FAT2 | c.6202C>T p.P2068S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55817755; called by muse, mutect2, varscan2
- FAT3 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766644775, COSV53074321; called by muse, mutect2, varscan2
- FAT3 | c.4093C>T p.P1365S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.94); catalogued as COSV53098915; called by muse, mutect2, varscan2
- FAT3 | c.11218G>A p.E3740K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.501); catalogued as rs377369099; called by muse, varscan2
- FBXO15 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV54044418; called by muse, mutect2, varscan2
- FBXO30 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 56/148 reads (38%) | catalogued as rs967349036, COSV52790809; called by muse, mutect2, varscan2
- FER1L5 | c.4137A>G p.P1379= (on ENST00000623019; = p.P1352= on NM_001293083.2) | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV67605987; called by muse, mutect2
- FGG | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV60195105; called by muse, mutect2, varscan2
- FIBIN | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.631); catalogued as rs766304964, COSV59412744, COSV59413529; called by muse, mutect2, varscan2
- FKBP15 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.298); catalogued as COSV99440249; called by muse, mutect2
- FMOD | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs916698838, COSV100724657; called by muse, mutect2, varscan2
- FOXJ1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV53943346; called by muse, mutect2
- FOXN1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as rs746183272, COSV56881416; called by muse, mutect2, varscan2
- FPGT | c.571T>G p.F191V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100907611; called by muse, mutect2, varscan2
- FREM1 | c.2989G>A p.G997R | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV66521899; called by muse, mutect2, varscan2
- FRY | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771312453, COSV66568488, COSV66570042; called by muse, mutect2, varscan2
- FSIP2 | c.16223C>T p.S5408L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV58079283, COSV58093971; called by muse, mutect2, varscan2
- FUBP1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs569612114, COSV53929392; called by muse, mutect2, varscan2
- FUT3 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1221003315, COSV54605435; called by muse, mutect2, varscan2
- G3BP2 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV100692972, COSV62976047; called by muse, mutect2, varscan2
- GABPA | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100702557; called by muse, mutect2, varscan2
- GABPA | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100702559; called by muse, mutect2, varscan2
- GABPA | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100702564, COSV61395987; called by muse, mutect2, varscan2
- GABRB3 | c.994T>A p.F332I | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV54659730; called by muse, mutect2, varscan2
- GABRB3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV54659758, COSV54677069; called by muse, mutect2
- GABRG1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54952607; called by muse, mutect2, varscan2
- GALNTL6 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72490507; called by muse, mutect2, varscan2
- GDPD4 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60018661; called by muse, mutect2, varscan2
- GEMIN4 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs775841183, COSV56745580; called by muse, mutect2, varscan2
- GNB4 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.24); catalogued as COSV51709105; called by muse, mutect2, varscan2
- GPAT4 | c.108T>A p.F36L | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV67840660; called by muse, mutect2, varscan2
- GPR137 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as COSV100464641; called by muse, mutect2, varscan2
- GPR158 | c.2317G>A p.D773N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs749643566, COSV66267551; called by muse, mutect2, varscan2
- GPR162 | c.1383G>C p.R461S (on ENST00000311268 / NM_019858.2; = p.R177S on NM_014449.2) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as COSV99301849; called by muse, mutect2, varscan2
- GPRC6A | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59952573; called by muse, mutect2, varscan2
- GRIN2A | c.3731A>G p.N1244S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV58028818; called by muse, mutect2, varscan2
- GSK3A | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV55898971; called by muse, mutect2, varscan2
- HAL | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV54117382; called by muse, mutect2, varscan2
- HECW1 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1404760029, COSV67826364; called by muse, mutect2, varscan2
- HELQ | c.1393T>C p.L465= | Splice Region (SNP) | VAF 17/57 reads (30%) | catalogued as COSV55024842; called by muse, mutect2, varscan2
- HERC2 | c.8567C>T p.S2856F | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55318594; called by muse, mutect2, varscan2
- HFM1 | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54025666; called by muse, mutect2, varscan2
- HHATL | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV60041498; called by muse, mutect2, varscan2
- HIVEP3 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56013621; called by muse, mutect2, varscan2
- HMSD | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1424123627, COSV68816884; called by muse, mutect2, varscan2
- HPD | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774495352, COSV56641675, COSV56643127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HS1BP3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV58312596; called by muse, mutect2, varscan2
- HS3ST2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1335261076, COSV54460634; called by muse, mutect2, varscan2
- HSD17B13 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV56345848, COSV56346424; called by muse, mutect2, varscan2
- HSP90AB1 | c.988A>T p.R330W | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62334062; called by muse, mutect2, varscan2
- HTR1E | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.066); catalogued as COSV100540810, COSV59507633; called by muse, mutect2, varscan2
- HTR1F | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60389447; called by muse, mutect2, varscan2
- HTR3C | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV59174941; called by muse, mutect2, varscan2
- HYDIN | c.15034G>A p.E5012K | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV66638434; called by muse, mutect2, varscan2
- HYDIN | c.7486G>A p.D2496N | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150902638; called by muse, varscan2
- ICAM4 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.638); catalogued as rs765755270, COSV53424506; called by muse, mutect2, varscan2
- ICE2 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV55030779; called by muse, mutect2, varscan2
- IDH1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV61621751; called by muse, mutect2, varscan2
- IDO2 | c.634C>T p.Q212* (on ENST00000389060; = p.Q225* on NM_194294.2) | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV58424570; called by muse, mutect2
- IGF1R | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1180612681, COSV51271054, COSV51279483, COSV51287490; called by muse, varscan2
- IL18 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199505901, COSV54780968; called by muse, mutect2
- IL1RL1 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as COSV52114854; called by muse, mutect2, varscan2
- IL4R | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs764099093, COSV50152115, COSV99405502; called by muse, mutect2, varscan2
- IL4R | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50195470; called by muse, mutect2, varscan2
- IQCN | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); catalogued as COSV66573628; called by muse, mutect2, varscan2
- IRX1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV57358475; called by muse, mutect2, varscan2
- ITGAV | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1445250226, COSV53711404; called by mutect2, varscan2
- ITGB5 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56148275, COSV56151832; called by muse, mutect2, varscan2
- JAKMIP2 | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54602032; called by muse, mutect2, varscan2
- KATNIP | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55191151; called by muse, mutect2, varscan2
- KATNIP | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs371104220; called by muse, mutect2, varscan2
- KCND3 | c.892T>A p.F298I | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56179010; called by muse, mutect2, varscan2
- KIF21B | c.3704G>A p.G1235E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV59755958; called by muse, mutect2, varscan2
- KIR3DL2 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54391045; called by muse, mutect2
- KIT | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs755508624, COSV55396430; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- KLHL2 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56976001; called by muse, mutect2, varscan2
- KMT2D | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV56429182; called by muse, mutect2, varscan2
- KRT80 | c.502C>T p.R168* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV57547549; called by muse, mutect2, varscan2
- LAMA1 | c.7684G>A p.D2562N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs772910533, COSV67535299; called by muse, mutect2, varscan2
- LAMA1 | c.1987C>T p.L663F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV67535301; called by muse, mutect2, varscan2
- LAMC3 | c.1165G>A p.G389S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63090231; called by muse, mutect2, varscan2
- LAT | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57954232; called by muse, mutect2, varscan2
- LCT | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 22/77 reads (29%) | catalogued as rs1167914907, COSV99919483; called by muse, mutect2, varscan2
- LMO7 | c.1741C>T p.P581S (on ENST00000357063; = p.P311S on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58533796; called by muse, mutect2, varscan2
- LMOD1 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1389129590, COSV66172413; called by muse, mutect2, varscan2
- LMOD1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV66172419; called by muse, mutect2, varscan2
- LRCH3 | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs755820100, COSV58391172; called by muse, mutect2, varscan2
- LRFN5 | c.1931A>T p.K644I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.383); catalogued as COSV53251896; called by muse, mutect2, varscan2
- LRG1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV56703292; called by muse, varscan2
- LRP1 | c.5467C>T p.L1823F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV99677933; called by muse, mutect2, varscan2
- LRP1B | c.4336T>G p.S1446A | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67206795; called by muse, mutect2, varscan2
- LRP1B | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV101261808, COSV67206799; called by mutect2, varscan2
- LRRC4B | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65349201; called by muse, mutect2, varscan2
- LRRC4C | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53422980; called by muse, varscan2
- LUC7L | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs772169832, COSV53457971; called by muse, mutect2, varscan2
- LY75 | c.3508-1G>A p.X1170_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as rs1383265638, COSV55104426; called by muse, mutect2, varscan2
- LYST | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); catalogued as COSV67706066; called by muse, mutect2, varscan2
- MACC1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60542045; called by muse, mutect2, varscan2
- MAGEC1 | c.1399C>A p.H467N | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53571210; called by muse, mutect2, varscan2
- MAJIN | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57262755; called by muse, mutect2, varscan2
- MAMDC4 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764179924, COSV99915983; called by muse, mutect2
- MAML1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1485874595, COSV52984567; called by muse, mutect2, varscan2
- MAML1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52984582; called by muse, mutect2, varscan2
- MAN1A2 | c.1286C>T p.A429V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV62977686; called by muse, mutect2, varscan2
- MAN2B1 | c.1530C>T p.F510= | Splice Region (SNP) | VAF 22/133 reads (17%) | catalogued as COSV55471407; called by muse, mutect2, varscan2
- MAP3K19 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV59637992; called by mutect2, varscan2
- MAP7 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63418940; called by muse, mutect2, varscan2
- MAPK1IP1L | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.005); catalogued as rs1175351178, COSV67106381; called by muse, mutect2, varscan2
- MARK2 | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV59282412; called by muse, mutect2, varscan2
- MAST1 | c.2763G>A p.M921I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV52244919; called by muse, mutect2, varscan2
- MBD5 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV68696232; called by muse, mutect2, varscan2
- MCF2 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV100645149, COSV58482622; called by muse, mutect2, varscan2
- MCF2L2 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1439517800, COSV61049919; called by muse, mutect2, varscan2
- MDGA2 | c.2281G>A p.G761R (on ENST00000399232 / NM_001113498.2; = p.G463R on NM_182830.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV62086987; called by mutect2, varscan2
- MED12 | c.5875C>T p.P1959S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.067); catalogued as COSV61336987, COSV61355778; called by muse, mutect2, varscan2
- MED24 | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV100673380; called by muse, mutect2, varscan2
- MEFV | c.188A>T p.E63V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561452; called by muse, varscan2
- MEFV | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54819747, COSV99561454; called by muse, varscan2
- MGAM | c.2056C>T p.H686Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073553; called by muse, mutect2
- MGAM | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 70/262 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72074445; called by muse, mutect2, varscan2
- MIA2 | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs754149612, COSV54482945; called by muse, mutect2, varscan2
- MKLN1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV61760547; called by muse, mutect2, varscan2
- MPHOSPH10 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs570909234, COSV54905478; called by muse, mutect2, varscan2
- MTHFR | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs201095365; called by muse, mutect2, varscan2
- MTX2 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV50887779, COSV50888572; called by muse, mutect2
- MUC16 | c.37418G>A p.R12473K | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV67459769; called by muse, mutect2, varscan2
- MUC16 | c.32425C>T p.R10809* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | catalogued as rs749875229, COSV67446949, COSV67480671; called by muse, mutect2, varscan2
- MUC16 | c.31502C>T p.P10501L | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV67443491, COSV67459781; called by muse, mutect2, varscan2
- MUC16 | c.30068C>T p.S10023F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs1454187826, COSV67459786; called by muse, mutect2, varscan2
- MUC16 | c.13490T>G p.L4497W | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.048); catalogued as COSV67459812; called by muse, mutect2, varscan2
- MUC16 | c.4958G>A p.G1653E | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs866942146, COSV67459824; called by muse, mutect2, varscan2
- MUC16 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); catalogued as rs533548881, COSV67444798; called by muse, mutect2, varscan2
- MUC5B | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs745507605, COSV71591335; called by muse, mutect2, varscan2
- MUS81 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.907); catalogued as COSV57259789; called by muse, mutect2, varscan2
- MXRA5 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV54231900; called by muse, mutect2, varscan2
- MYBBP1A | c.2924C>G p.T975S | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.107); catalogued as COSV54596623; called by muse, mutect2, varscan2
- MYH1 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs777717443, COSV56846687; called by muse, mutect2, varscan2
- MYH14 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.037); catalogued as COSV51814934; called by muse, mutect2, varscan2
- MYH7B | c.4280C>T p.A1427V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1359206247, COSV52678821; called by muse, mutect2, varscan2
- MYO16 | c.2843C>T p.S948L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs45520342, COSV51779154, COSV51787953; called by muse, mutect2, varscan2
- MYOCD | c.1930A>T p.K644* | Nonsense Mutation (SNP) | VAF 31/125 reads (25%) | catalogued as COSV58501839; called by muse, mutect2, varscan2
- NAV2 | c.3659G>A p.S1220N (on ENST00000396087 / NM_001244963.2; = p.S1197N on NM_145117.5) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60658456; called by muse, mutect2, varscan2
- NAV2 | c.5464G>A p.D1822N (on ENST00000396087 / NM_001244963.2; = p.D1766N on NM_145117.5) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV60658467; called by muse, mutect2, varscan2
- NDRG4 | c.853G>A p.G285S (on ENST00000570248 / NM_001378344.1; = p.G317S on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50747233; called by muse, mutect2, varscan2
- NDST4 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52115889; called by muse, mutect2, varscan2
- NEBL | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs372364915; called by muse, mutect2
- NEFH | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.02); catalogued as COSV60216454; called by muse, mutect2, varscan2
- NEGR1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.02); catalogued as COSV60840817; called by muse, mutect2, varscan2
- NEK2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV65355771; called by muse, mutect2, varscan2
- NFATC2 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 53/246 reads (22%) | catalogued as COSV65354643; called by muse, mutect2, varscan2
- NIPAL1 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as COSV55006269; called by muse, mutect2, varscan2
- NLRC3 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs766682147, COSV57089666; called by muse, mutect2, varscan2
- NOC2L | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100498246; called by muse, mutect2, varscan2
- NOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1371565397, COSV56115028; called by muse, mutect2, varscan2
- NOSTRIN | c.856G>A p.E286K (on ENST00000317647 / NM_001039724.4; = p.E208K on NM_052946.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV58320708; called by muse, mutect2
- NPAS4 | c.905G>A p.G302D | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as COSV60649913; called by muse, mutect2, varscan2
- NPR1 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs772350188, COSV64117489; called by muse, mutect2, varscan2
- NRIP1 | c.2980T>G p.C994G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV59656738; called by muse, mutect2, varscan2
- NUDT12 | c.743A>T p.Y248F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.021); catalogued as COSV50090765; called by muse, mutect2, varscan2
- NUGGC | c.173G>A p.R58K | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV58434032; called by muse, mutect2, varscan2
- NUP210L | c.2459G>A p.W820* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55145882; called by muse, mutect2, varscan2
- OAS2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs769730827, COSV60802067; called by muse, mutect2, varscan2
- OAS2 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.355); catalogued as COSV100660377; called by muse, mutect2, varscan2
- ODF2L | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as rs1377492106, COSV54015031; called by mutect2, varscan2
- OGA | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63381463; called by muse, mutect2, varscan2
- OPLAH | c.3184C>T p.P1062S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70677762, COSV70679275; called by muse, mutect2, varscan2
- OR10R2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1352239072, COSV63768728; called by muse, mutect2, varscan2
- OR13G1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV62943525; called by muse, mutect2, varscan2
- OR1S1 | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1263816515, COSV58706778, COSV58707656; called by muse, mutect2, varscan2
- OR2T4 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63543758, COSV63544321; called by muse, mutect2, varscan2
- OR2Y1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs199524214, COSV57136447; called by muse, mutect2, varscan2
- OR4P4 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV58920526; called by muse, mutect2, varscan2
- OR51G2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58991807; called by muse, mutect2, varscan2
- OR52M1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as rs991109848, COSV64171844, COSV64172186; called by muse, mutect2, varscan2
- OR5I1 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV56886384, COSV56887803; called by muse, mutect2, varscan2
- OR5P2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV100271304, COSV61490337; called by muse, mutect2, varscan2
- OR5T1 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV57302356; called by muse, mutect2, varscan2
- OR8B3 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100660385, COSV63541581; called by muse, mutect2, varscan2
- OR8B8 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.297); catalogued as COSV60144336; called by muse, mutect2, varscan2
- OSBPL10 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 30/151 reads (20%) | catalogued as COSV67338307; called by muse, mutect2, varscan2
- OTOGL | c.575G>A p.R192Q (on ENST00000547103; = p.R183Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs540892936, COSV72006457, COSV72007011; called by muse, mutect2
- OTOGL | c.982C>T p.P328S (on ENST00000547103; = p.P319S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72006458; called by muse, mutect2, varscan2
- PADI2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV64945661; called by muse, mutect2, varscan2
- PANK1 | c.796G>A p.E266K (on ENST00000307534 / NM_148977.2; = p.E41K on NM_138316.4) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100285909; called by muse, mutect2, varscan2
- PAPPA2 | c.4159C>T p.H1387Y | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV62791433; called by muse, mutect2, varscan2
- PARN | c.1453C>T p.L485F | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100421502; called by muse, mutect2, varscan2
- PARP3 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762278473, COSV51753358; called by muse, mutect2, varscan2
- PAX5 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63906595; called by muse, mutect2
- PAXX | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100860495; called by muse, mutect2, varscan2
- PCDHA11 | c.359A>T p.N120I | Missense Mutation (SNP) | VAF 62/236 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); catalogued as COSV100256098; called by muse, mutect2, varscan2
- PCDHA6 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65350136; called by muse, varscan2
- PCDHB10 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53377769; called by muse, mutect2, varscan2
- PCDHB6 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50692825, COSV50693880; called by muse, mutect2, varscan2
- PCDHB8 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV50761908; called by muse, mutect2, varscan2
- PCLO | c.14411G>A p.G4804E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439692; called by muse, mutect2, varscan2
- PCLO | c.14410G>T p.G4804W | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439693; called by muse, mutect2, varscan2
- PDE1A | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.258); catalogued as rs751941346, COSV59520607; called by muse, mutect2, varscan2
- PDE2A | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); catalogued as COSV57805225; called by muse, mutect2, varscan2
- PDE4DIP | c.1288C>T p.R430* | Nonsense Mutation (SNP) | VAF 25/156 reads (16%) | catalogued as rs782276593, COSV57690531, COSV57711047; called by muse, mutect2, varscan2
- PGAP3 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs745713528, COSV99510508, COSV99510860; called by muse, mutect2, varscan2
- PHACTR2 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as rs1004477333, COSV59853715; called by muse, mutect2, varscan2
- PHGDH | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.667); catalogued as COSV65570697; called by muse, mutect2, varscan2
- PID1 | c.439C>T p.H147Y (on ENST00000354069 / NM_001330156.1; = p.H145Y on NM_017933.5) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.992); catalogued as COSV62474008; called by muse, mutect2, varscan2
- PIGT | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1218912444; called by muse, mutect2
- PIP5K1B | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV99600125; called by muse, mutect2, varscan2
- PKN1 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as COSV54396921; called by muse, mutect2, varscan2
- PLA2G4A | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66553324; called by muse, varscan2
- PLA2G4D | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV51820168; called by muse, mutect2, varscan2
- PLEKHG3 | c.936C>G p.S312R (on ENST00000394691; = p.S368R on NM_001308147.2) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV55979153; called by muse, mutect2
- PLEKHH2 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752220; called by muse, mutect2, varscan2
- PLSCR3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314493332, COSV61170445; called by muse, mutect2, varscan2
- PMPCB | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV50785808; called by muse, mutect2, varscan2
- PNMA5 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62625503; called by muse, mutect2, varscan2
- POLA1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as COSV66885414; called by muse, mutect2, varscan2
- POLR3GL | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV65215363; called by muse, mutect2, varscan2
- PPFIA1 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as COSV99558217; called by muse, mutect2, varscan2
- PPFIBP2 | c.1864A>G p.K622E | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.981); catalogued as rs751855172, COSV55076197; called by muse, mutect2, varscan2
- PRPF40B | c.2485C>T p.P829S (on ENST00000380281; = p.P816S on NM_012272.3) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99527277; called by muse, mutect2, varscan2
- PRPF40B | c.2486C>T p.P829L (on ENST00000380281; = p.P816L on NM_012272.3) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1262918092; called by muse, mutect2, varscan2
- PSG5 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV61654021; called by muse, mutect2, varscan2
- PTBP3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV57581991; called by muse, mutect2, varscan2
- PTGDS | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV56400173; called by muse, mutect2, varscan2
- PTH1R | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM1313663, COSV57314554; called by muse, mutect2, varscan2
- PTPN22 | c.2228G>A p.G743E (on ENST00000359785 / NM_001193431.2; = p.G688E on NM_012411.5) | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV63084808; called by muse, mutect2, varscan2
- PTPRT | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV61963224; called by muse, mutect2
- PUS3 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV57102772, COSV99916711; called by mutect2, varscan2
- RAB30 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52625818, COSV99475999; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV52786393, COSV99216546; called by muse, mutect2, varscan2
- RAPGEF4 | c.2053C>T p.R685W | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs368051118; called by muse, varscan2
- RAPH1 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV99864811; called by muse, mutect2, varscan2
- RASAL3 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.799); catalogued as COSV59139132; called by muse, mutect2, varscan2
- RASSF4 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58485719; called by muse, varscan2
- RBAK | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100806811; called by muse, mutect2, varscan2
- RBP2 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as rs1042111373, COSV99218554; called by muse, mutect2, varscan2
- RBP7 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1241384176, COSV53812870; called by muse, mutect2, varscan2
- RELN | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); catalogued as COSV58996589; called by muse, mutect2, varscan2
- REXO1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1275635518, COSV50076731; called by muse, mutect2, varscan2
- RFFL | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs781337074, COSV52071344; called by muse, mutect2, varscan2
- RIPK1 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1349768817, COSV52528270; called by muse, mutect2, varscan2
- RNASE10 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.759); catalogued as rs990849965, COSV60517634; called by muse, mutect2, varscan2
- RNF112 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1385733257, COSV71327029; called by muse, mutect2, varscan2
- RNPEP | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55240403; called by muse, mutect2, varscan2
- RORA | c.1408T>G p.L470V (on ENST00000335670 / NM_134261.3; = p.L495V on NM_002943.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV55037941; called by muse, mutect2
- RPUSD2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1334685907, COSV59765221; called by muse, mutect2, varscan2
- RTN4 | c.1687T>A p.L563M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV58266639; called by muse, mutect2, varscan2
- RTN4RL2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV58651823; called by muse, mutect2, varscan2
- RTTN | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.178); catalogued as COSV55343635; called by muse, mutect2, varscan2
- RXFP3 | c.1157C>A p.P386H | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57505084, COSV57505131; called by muse, mutect2, varscan2
- RYR1 | c.8039G>A p.W2680* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV62094654; called by muse, mutect2, varscan2
- SARS1 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 38/204 reads (19%) | catalogued as rs770711538, COSV52321337; called by muse, varscan2
- SATB1 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58668639; called by muse, mutect2, varscan2
- SCAF4 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV99532308; called by muse, mutect2, varscan2
- SCAF4 | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.335); catalogued as COSV99532309; called by muse, mutect2, varscan2
- SCEL | c.1642G>A p.E548K (on ENST00000349847 / NM_144777.3; = p.E528K on NM_003843.4) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs776379294, COSV62993302; called by muse, mutect2, varscan2
- SCNN1G | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100264623; called by muse, varscan2
- SDC3 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59579147; called by muse, mutect2, varscan2
- SDHC | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV61367918; called by muse, varscan2
- SEC14L3 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as rs940031734, COSV99307356; called by muse, mutect2
- SEC16A | c.5615C>T p.A1872V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV51525670; called by muse, mutect2, varscan2
- SEC16A | c.2549C>T p.S850L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1289205763, COSV51525688; called by muse, mutect2
- SERPINA12 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV57943155; called by muse, mutect2, varscan2
- SERPINC1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV62929169; called by muse, mutect2, varscan2
- SGCA | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.37); catalogued as rs780564461, COSV56248957; called by muse, mutect2, varscan2
- SH3TC1 | c.1456T>G p.C486G | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.236); catalogued as COSV55283372; called by muse, mutect2
- SHC3 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); catalogued as COSV65437891; called by muse, mutect2, varscan2
- SHE | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV59071456; called by muse, mutect2, varscan2
- SI | c.4037C>T p.T1346I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs750118266, COSV52274140; called by muse, mutect2, varscan2
- SIGLEC1 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV52461936; called by muse, mutect2, varscan2
- SIGLEC7 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV58315356; called by muse, mutect2, varscan2
- SIPA1L3 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV55912431; called by muse, mutect2
- SKOR1 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58245164; called by muse, mutect2, varscan2
- SLC10A2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55358246; called by muse, mutect2
- SLC13A2 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs781976085, COSV58992843; called by muse, mutect2, varscan2
- SLC13A4 | c.1319G>A p.G440E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV100819004; called by muse, mutect2, varscan2
- SLC13A4 | c.1319-1G>A p.X440_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100818764, COSV100819005; called by muse, mutect2, varscan2
- SLC14A2 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs148232674; called by muse, mutect2, varscan2
- SLC22A14 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV56197281; called by muse, mutect2, varscan2
- SLC25A23 | c.534A>T p.Q178H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs775634908, COSV51191058; called by muse, mutect2, varscan2
- SLC26A8 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs142738122; called by muse, mutect2, varscan2
- SLC34A2 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs552759498, COSV65941266; called by muse, mutect2
- SLC35F3 | c.402-1G>A p.X134_splice (on ENST00000366617 / NM_001300845.1; = p.X203_splice on NM_173508.4) | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as rs1344362857; called by muse, mutect2
- SLC35F3 | c.402G>A p.R134= (on ENST00000366617 / NM_001300845.1; = p.R203= on NM_173508.4) | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100784903; called by muse, mutect2
- SLC38A4 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1417160761, COSV56966698; called by muse, mutect2, varscan2
- SLC39A4 | c.1764G>A p.W588* (on ENST00000301305 / NM_001374839.1; = p.W563* on NM_017767.3) | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | catalogued as COSV52778511; called by muse, mutect2, varscan2
- SLC6A13 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58256680; called by muse, mutect2, varscan2
- SLC6A7 | c.1333G>A p.G445R | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs763263062, COSV57937761; called by muse, mutect2, varscan2
- SLC8A3 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV63520447; called by muse, varscan2
- SLC8A3 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100776216, COSV63520455; called by muse, varscan2
- SLTM | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as rs771061663, COSV65848623; called by muse, mutect2, varscan2
- SMARCE1 | c.338A>G p.Q113R | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV52860858; called by muse, mutect2, varscan2
- SMU1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV68139770; called by muse, mutect2, varscan2
- SNAP91 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52120121; called by muse, mutect2, varscan2
- SNTG2 | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV57977418; called by muse, mutect2, varscan2
- SNX13 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68064634; called by muse, mutect2, varscan2
- SP2 | c.1475G>A p.G492E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.933); catalogued as COSV65063843; called by muse, mutect2, varscan2
- SPAG17 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV60456846; called by muse, mutect2, varscan2
- SPATA31D1 | c.730C>G p.P244A | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61194730, COSV61196808; called by muse, mutect2, varscan2
- SPATA31D1 | c.4321G>A p.A1441T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61194741; called by muse, mutect2, varscan2
- SPATA31E1 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs780597687, COSV100350624, COSV57789681; called by muse, mutect2, varscan2
- SPSB1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60162878, COSV60163172; called by muse, mutect2, varscan2
- SPTY2D1 | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60473568; called by muse, mutect2, varscan2
- SRGAP3 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV64532312; called by muse, mutect2, varscan2
- ST18 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs867547514, COSV52490872; called by muse, mutect2, varscan2
- ST3GAL1 | c.418C>G p.R140G | Missense Mutation (SNP) | VAF 32/91 reads (35%) | PolyPhen possibly damaging (0.682); catalogued as COSV100172766, COSV60611943; called by muse, mutect2, varscan2
- STAB2 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV66336767, COSV66336865; called by muse, mutect2, varscan2
- STAB2 | c.4904C>T p.P1635L | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66337747; called by muse, mutect2, varscan2
- STARD13 | c.2420C>T p.P807L (on ENST00000336934 / NM_001243476.3; = p.P689L on NM_052851.3) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV55229484; called by muse, mutect2, varscan2
- STK10 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1355128107, COSV99452544; called by muse, mutect2, varscan2
- STOML1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.515); catalogued as COSV57551398; called by muse, mutect2, varscan2
- STRIP2 | c.1618A>C p.I540L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50803872; called by muse, mutect2, varscan2
- STXBP2 | c.1494C>G p.F498L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV55402812, COSV55403463; called by muse, mutect2, varscan2
- STXBP5L | c.3311C>T p.S1104L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs763793317, COSV56509585; called by mutect2, varscan2
- SULT1A1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768899038, COSV59087416; called by muse, mutect2, varscan2
- SULT1C3 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs753480643, COSV61252754; called by muse, mutect2, varscan2
- SUMO4 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53852115; called by muse, mutect2, varscan2
- SV2C | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV100457025; called by muse, mutect2, varscan2
- SYNE1 | c.13127C>T p.P4376L (on ENST00000367255 / NM_182961.4; = p.P4305L on NM_033071.3) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1158916845, COSV54957435; called by muse, mutect2, varscan2
- SYNJ2 | c.3194A>G p.H1065R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV62896799; called by muse, mutect2, varscan2
- TACC1 | c.2206C>T p.H736Y | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52523178; called by muse, mutect2, varscan2
- TAF2 | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV65417647; called by muse, mutect2, varscan2
- TANC1 | c.2189C>T p.P730L | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55086437; called by muse, mutect2, varscan2
- TBC1D2B | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100317925; called by muse, varscan2
- TCF20 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.997); catalogued as COSV59490307; called by muse, mutect2, varscan2
- TEC | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67404416, COSV99060804; called by muse, mutect2, varscan2
- TECPR2 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63969962; called by muse, mutect2, varscan2
- TENM2 | c.4099G>A p.G1367R (on ENST00000518659 / NM_001122679.2; = p.G1128R on NM_001080428.3) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV69127795; called by muse, mutect2, varscan2
- TEPSIN | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56142400; called by mutect2, varscan2
- TGIF2 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65836400; called by muse, mutect2, varscan2
- THSD4 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV55966515, COSV99964405; called by muse, mutect2
- THSD7B | c.148G>A p.G50R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55649244; called by muse, mutect2, varscan2
- TLL1 | c.903G>C p.R301S | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV50272544, COSV50331739; called by mutect2, varscan2
- TLR5 | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV60558661; called by muse, mutect2, varscan2
- TLR6 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67935151; called by muse, mutect2
- TMC5 | c.2159C>T p.S720F (on ENST00000396229 / NM_001105248.1; = p.S474F on NM_024780.5) | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs1405032739, COSV99060538, COSV99573008; called by muse, mutect2, varscan2
- TMEM131L | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs368692455; called by muse, mutect2, varscan2
- TMEM132B | c.2923G>A p.G975S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV54750862; called by muse, mutect2, varscan2
- TMEM132D | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1485337608, COSV67159870, COSV67160022; called by muse, mutect2, varscan2
- TMEM156 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.022); catalogued as COSV67929177; called by muse, mutect2, varscan2
- TMEM161A | c.1185G>T p.L395= | Splice Region (SNP) | VAF 21/80 reads (26%) | catalogued as COSV50776428; called by muse, mutect2, varscan2
- TMEM67 | c.2179del p.Y727Ifs*5 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV60040957; called by mutect2, pindel, varscan2
- TMPRSS9 | c.724G>A p.E242K (on ENST00000648592; = p.E208K on NM_182973.2) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV60226906; called by muse, mutect2, varscan2
- TNC | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs965522543, COSV60781345; called by muse, mutect2, varscan2
- TOMM40L | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV63467645; called by muse, mutect2, varscan2
- TOP2B | c.3526C>T p.L1176F (on ENST00000264331 / NM_001330700.2; = p.L1171F on NM_001068.3) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51970848; called by muse, mutect2, varscan2
- TP53BP1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55499490; called by muse, mutect2, varscan2
- TPH1 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51457769; called by muse, mutect2, varscan2
- TPX2 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 18/118 reads (15%) | catalogued as rs267605874, COSV55917843; called by muse, mutect2, varscan2
- TREML4 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58384864; called by muse, mutect2, varscan2
- TRIM11 | c.1144T>G p.F382V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV52857336; called by muse, mutect2, varscan2
- TRIM21 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as COSV54343787; called by muse, mutect2, varscan2
- TRIM67 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV64158628; called by muse, mutect2, varscan2
- TRIP12 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52262280; called by muse, mutect2
- TRNT1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52408014; called by muse, mutect2, varscan2
- TRPC4 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.065); catalogued as rs770256915, COSV58997246; called by muse, mutect2, varscan2
- TSPY2 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs749845353, COSV57836994; called by muse, mutect2, varscan2
- TSR1 | c.1733C>T p.P578L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV56784686; called by muse, mutect2, varscan2
- TTLL9 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs1351697390, COSV60591217; called by muse, mutect2, varscan2
- TTN | c.72148G>A p.D24050N (on ENST00000591111; = p.D16626N on NM_003319.4) | Missense Mutation (SNP) | VAF 24/105 reads (23%) | PolyPhen possibly damaging (0.526); catalogued as COSV59992886; called by muse, mutect2, varscan2
- TTN | c.23062G>A p.E7688K (on ENST00000591111; = p.E6761K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | PolyPhen possibly damaging (0.722); catalogued as COSV59992918; called by muse, mutect2, varscan2
- TTN | c.11728A>G p.T3910A (on ENST00000591111; = p.T3864A on NM_003319.4) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100635262; called by muse, mutect2, varscan2
- TUBB8 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV59115368; called by muse, mutect2, varscan2
- UBE4A | c.2089C>T p.P697S (on ENST00000252108 / NM_001204077.2; = p.P704S on NM_004788.4) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs1555126520, COSV52803668; called by muse, mutect2, varscan2
- UBN1 | c.3262C>T p.H1088Y | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99278839; called by muse, mutect2, varscan2
- UBXN4 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.115); catalogued as COSV55634447; called by muse, mutect2, varscan2
- UGT1A4 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100531411, COSV59386934; called by muse, mutect2, varscan2
- UGT2A3 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV52359647; called by muse, mutect2, varscan2
- UGT2B10 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55319831; called by muse, mutect2, varscan2
- UNC13C | c.4726G>A p.D1576N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.654); catalogued as rs1486422031, COSV52849589; called by muse, mutect2, varscan2
- UNC79 | c.6055G>A p.D2019N (on ENST00000393151 / NM_001346218.2; = p.D1842N on NM_020818.5) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs778086735, COSV56383035; called by muse, mutect2, varscan2
- USF3 | c.5971C>T p.R1991C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200190750, COSV57071633; called by muse, mutect2, varscan2
- USP29 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV54238296, COSV54238896; called by muse, mutect2
- USP3 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1243983170, COSV99165841; called by muse, mutect2, varscan2
- USP7 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61214125; called by muse, mutect2, varscan2
- USPL1 | c.1541T>C p.L514P | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV54999534; called by muse, mutect2, varscan2
- VCAN | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV54102979; called by muse, mutect2, varscan2
- VCAN | c.4443G>A p.W1481* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV54102991; called by muse, mutect2, varscan2
- VIL1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.281); catalogued as COSV50287036; called by muse, mutect2, varscan2
- VPS13A | c.4992A>G p.I1664M | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62428143; called by muse, mutect2, varscan2
- WNK4 | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs750022775, COSV55907134; called by muse, mutect2, varscan2
- WNT3A | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs745831522, COSV52730400; called by muse, mutect2, varscan2
- WWP2 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598870; called by muse, mutect2, varscan2
- YIF1A | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs774576544, COSV100268346, COSV100268600; called by muse, mutect2, varscan2
- ZBED9 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV71729317; called by muse, mutect2, varscan2
- ZDHHC23 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57629287; called by muse, mutect2, varscan2
- ZFHX3 | c.8798C>T p.S2933F | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764820113, COSV51715203, COSV51742892; called by muse, mutect2, varscan2
- ZFR | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.558); catalogued as COSV54052191; called by muse, mutect2, varscan2
- ZNF106 | c.4978A>G p.S1660G | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55515686; called by muse, mutect2, varscan2
- ZNF114 | c.1228C>T p.H410Y | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59944050; called by muse, mutect2, varscan2
- ZNF136 | c.1474C>T p.R492* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as rs752780410, COSV59710631; called by muse, mutect2, varscan2
- ZNF23 | c.1072C>T p.H358Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1237389344, COSV100612081, COSV61840800; called by muse, mutect2, varscan2
- ZNF263 | c.2008C>T p.R670W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.94); catalogued as rs1253237931, COSV54596119; called by muse, mutect2, varscan2
- ZNF317 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV56109212; called by muse, mutect2, varscan2
- ZNF333 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV52885602; called by muse, mutect2, varscan2
- ZNF433 | c.145A>T p.K49* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV61398972; called by muse, mutect2, varscan2
- ZNF454 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV60768019; called by muse, mutect2, varscan2
- ZNF479 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV58637717; called by muse, mutect2, varscan2
- ZNF507 | c.1322T>C p.V441A | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs541497402, COSV61330795; called by muse, mutect2, varscan2
- ZNF536 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV62822438; called by muse, mutect2, varscan2
- ZNF550 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 72/384 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV100286932; called by muse, mutect2, varscan2
- ZNF579 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.24); catalogued as rs779941802, COSV57637686; called by muse, mutect2
- ZNF585B | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.766); catalogued as COSV57215150; called by muse, mutect2, varscan2
- ZNF598 | c.2525G>A p.S842N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV50192183; called by muse, mutect2, varscan2
- ZNF609 | c.3772T>G p.S1258A | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.328); catalogued as COSV58582148; called by muse, mutect2, varscan2
- ZNF618 | c.2614A>G p.N872D (on ENST00000374126 / NM_001318042.2; = p.N779D on NM_133374.2) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as COSV55919850; called by muse, mutect2, varscan2
- ZNF638 | c.4252C>T p.P1418S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52496792; called by muse, mutect2, varscan2
- ZNF638 | c.4253C>T p.P1418L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1306002319, COSV100040388; called by muse, mutect2, varscan2
- ZNF660 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs977750373, COSV59548852; called by muse, mutect2, varscan2
- ZNF676 | c.1255C>T p.H419Y (on ENST00000650058; = p.H387Y on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV68092802, COSV68094887; called by muse, mutect2, varscan2
- ZNF683 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs761991706, COSV100853770; called by muse, mutect2, varscan2
- ZNF692 | c.233A>G p.K78R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV60659107; called by muse, mutect2, varscan2
- ZNF699 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58025320; called by muse, mutect2, varscan2
- ZNF777 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 64/289 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56097114; called by muse, mutect2, varscan2
- ZNF777 | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV56097123; called by muse, mutect2, varscan2
- ZNF808 | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100708228, COSV63119339; called by muse, mutect2, varscan2
- ZNF93 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV59375083; called by muse, mutect2, varscan2
- ZYX | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV51970431; called by muse, mutect2, varscan2
- BOP1 | c.2149C>T p.R717* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- C1GALT1C1L | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- C1GALT1C1L | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- CADPS2 | c.885_889del p.K295Nfs*37 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- CHN1 | c.1080_1084del p.Y360* | Nonsense Mutation (DEL) | VAF 37/216 reads (17%) | called by mutect2, pindel, varscan2
- GPR179 | c.2989G>A p.E997K (on ENST00000621958; = p.E996K on NM_001004334.4) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-2 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- IGHV3-35 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP1B | c.2234_2236del p.P745del | In Frame Del (DEL) | VAF 24/120 reads (20%) | called by pindel, varscan2
- MLLT6 | c.2353+1G>T p.X785_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2
- MUC2 | c.2204G>A p.G735E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- RTN1 | c.336_344dup p.C113_P115dup | In Frame Ins (INS) | VAF 8/41 reads (20%) | called by mutect2, varscan2
- TAF15 | c.643C>T p.H215Y (on ENST00000605844 / NM_139215.3; = p.H212Y on NM_003487.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ABCC11 | c.1470C>T p.I490= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as rs139456533; called by muse, mutect2, varscan2
- ACSF2 | c.735C>T p.L245= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs141937528; called by muse, mutect2, varscan2
- ACSL1 | c.870C>T p.H290= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV55662006; called by muse, mutect2, varscan2
- ADAMTS1 | c.2013C>T p.F671= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs138450833; called by muse, mutect2, varscan2
- ADAMTSL4 | c.300G>A p.Q100= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV54998710; called by muse, mutect2, varscan2
- ADGRE2 | c.495T>C p.N165= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as COSV59692908; called by muse, mutect2, varscan2
- ADGRF4 | c.1890C>T p.S630= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV99349132; called by muse, mutect2, varscan2
- AGRN | c.351G>A p.V117= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as COSV65068997; called by muse, mutect2, varscan2
- ALB | c.882G>A p.S294= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs143665140, COSV99891576; called by muse, mutect2, varscan2
- ALOX15B | c.159C>T p.F53= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV66479314; called by muse, mutect2, varscan2
- ANKEF1 | c.2202G>A p.E734= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs777080365, COSV65692271, COSV65693018; called by muse, mutect2, varscan2
- ANKH | c.477C>T p.F159= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs866554190, COSV52477289; called by muse, mutect2, varscan2
- ANKRD24 | c.1833C>T p.T611= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs775072240, COSV53669556; called by muse, mutect2, varscan2
- APEH | c.210C>T p.F70= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56516121; called by muse, mutect2, varscan2
- APOBR | c.2544C>T p.P848= (on ENST00000431282; = p.P857= on NM_018690.4) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1394411353, COSV60489981; called by muse, mutect2, varscan2
- ARHGAP31 | c.456C>T p.H152= | Silent (SNP) | VAF 36/142 reads (25%) | catalogued as COSV99957980; called by muse, mutect2, varscan2
- ARHGAP31 | c.457C>T p.L153= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV99957981; called by muse, mutect2, varscan2
- ARHGAP6 | c.939T>A p.A313= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV57294597; called by muse, mutect2, varscan2
- ASAP3 | c.1992G>A p.K664= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV60874178; called by muse, mutect2, varscan2
- ATF6B | c.1362C>T p.L454= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV64351656; called by muse, mutect2, varscan2
- ATP13A5 | c.1350G>A p.L450= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV60868242; called by muse, mutect2, varscan2
- ATP2C2 | c.1524C>T p.F508= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as rs770069464, COSV52294686; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2199C>T p.S733= (on ENST00000343619 / NM_001378531.1; = p.S727= on NM_005177.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as COSV99231804; called by muse, mutect2, varscan2
- ATXN1 | c.1566C>T p.F522= | Silent (SNP) | VAF 49/225 reads (22%) | catalogued as rs368453524; called by muse, mutect2, varscan2
- BCAM | c.735G>A p.E245= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV54301727; called by muse, mutect2, varscan2
- BCCIP | c.573C>T p.I191= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs143179971; called by muse, mutect2, varscan2
- BCL9L | c.3063C>T p.S1021= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV52683546; called by muse, mutect2, varscan2
- BCOR | c.1956C>T p.P652= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1238401017, COSV60705203; called by muse, mutect2, varscan2
- BOP1 | c.2148C>T p.T716= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- BOP1 | c.1989G>A p.K663= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- BPIFA3 | c.273G>A p.E91= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV64925762; called by muse, mutect2, varscan2
- BPTF | c.2871T>C p.V957= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV58835387; called by muse, mutect2, varscan2
- BUD23 | c.105C>T p.I35= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as COSV56094779; called by muse, mutect2, varscan2
- C16orf71 | c.324G>A p.Q108= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV54794890; called by muse, mutect2, varscan2
- C1QTNF12 | c.183C>T p.S61= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV57802514; called by muse, mutect2, varscan2
- C5AR1 | c.676C>T p.L226= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as COSV61892450; called by muse, mutect2, varscan2
- CACHD1 | c.1335C>T p.N445= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs575705380, COSV51551843; called by muse, mutect2, varscan2
- CAVIN2 | c.1071G>A p.E357= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV58423844; called by muse, mutect2, varscan2
- CCDC87 | c.2316C>T p.L772= | Silent (SNP) | VAF 50/177 reads (28%) | catalogued as rs904654444, COSV59578786; called by muse, mutect2, varscan2
- CCDC88B | c.4140C>T p.S1380= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV53702222; called by muse, mutect2
- CCDC9 | c.1383C>T p.P461= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99699935; called by muse, mutect2, varscan2
- CD55 | c.921A>G p.T307= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs770776402, COSV58576785; called by muse, mutect2, varscan2
- CDH15 | c.1143G>A p.R381= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs374563128; called by muse, mutect2, varscan2
- CEP44 | c.432T>C p.P144= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99639898; called by muse, mutect2, varscan2
- CHD6 | c.1545C>T p.I515= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs149970572; called by muse, mutect2, varscan2
- CHRFAM7A | c.486C>T p.F162= | Silent (SNP) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- CKMT2 | c.91C>T p.L31= | Silent (SNP) | VAF 51/257 reads (20%) | catalogued as COSV54172847; called by muse, mutect2, varscan2
- CLU | c.960G>A p.Q320= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV57066372; called by muse, mutect2
- CNGB3 | c.57G>A p.E19= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV60688144; called by muse, mutect2, varscan2
- COL7A1 | c.2913G>A p.S971= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs370519980; called by muse, mutect2, varscan2
- COMP | c.405C>G p.P135= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55874384; called by muse, mutect2
- CRY2 | c.1374C>T p.F458= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs999631131, COSV101314629; called by muse, mutect2, varscan2
- CSPG4 | c.327C>T p.P109= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs751465567, COSV57893619; called by muse, mutect2, varscan2
- CUEDC1 | c.90C>T p.P30= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs754576076, COSV64226317; called by muse, mutect2, varscan2
- CUX1 | c.903G>A p.Q301= (on ENST00000292535 / NM_181552.4; = p.Q312= on NM_001913.5) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV52896546; called by muse, mutect2, varscan2
- CYBB | c.358C>T p.L120= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV66085191; called by muse, mutect2, varscan2
- CYBB | c.1404G>A p.R468= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66085195; called by muse, mutect2, varscan2
- CYP19A1 | c.48C>T p.I16= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs375851874; called by muse, varscan2
- CYP4F22 | c.1131G>A p.L377= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV54107911; called by muse, mutect2
- CYP4F8 | c.672G>A p.A224= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs1170374494, COSV57853819, COSV57854631; called by muse, mutect2, varscan2
- DAAM2 | c.2775C>T p.S925= (on ENST00000274867 / NM_001201427.2; = p.S924= on NM_015345.3) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs754385047, COSV51309368; called by muse, mutect2, varscan2
- DAB1 | c.1458A>C p.A486= (on ENST00000371231; = p.A453= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as COSV64692280; called by muse, mutect2, varscan2
- DCST2 | c.780C>T p.P260= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1388584395, COSV55051128; called by muse, mutect2, varscan2
- DDO | c.585G>A p.K195= (on ENST00000368924 / NM_001368172.1; = p.K136= on NM_004032.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/125 reads (36%) | catalogued as COSV64469994; called by muse, mutect2, varscan2
- DEPDC1 | c.1659C>T p.L553= | Silent (SNP) | VAF 25/162 reads (15%) | catalogued as rs763446549, COSV63958046; called by muse, mutect2, varscan2
- DEUP1 | c.1578G>A p.S526= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs780369481, COSV53211422; called by muse, mutect2, varscan2
- DLGAP3 | c.2865C>T p.S955= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV52393249; called by muse, mutect2, varscan2
- DLGAP4 | c.261C>T p.P87= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs267605912, COSV59416809; called by muse, mutect2, varscan2
- DPYD | c.2046G>A p.L682= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1420425419, COSV100928893, COSV64595069; called by muse, mutect2, varscan2
- DTL | c.792C>T p.Y264= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100877309; called by muse, mutect2, varscan2
- E2F8 | c.2562C>T p.V854= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV51462930; called by muse, mutect2, varscan2
- E2F8 | c.1560C>T p.S520= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV51462941; called by muse, mutect2, varscan2
- ECRG4 | c.183C>T p.F61= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as COSV53000627; called by muse, mutect2, varscan2
- EEPD1 | c.912C>T p.D304= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV54197266; called by muse, mutect2, varscan2
- ELN | c.246C>T p.F82= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV52709470; called by muse, mutect2, varscan2
- EPHB2 | c.2097C>T p.T699= (on ENST00000400191 / NM_001309193.2; = p.T700= on NM_004442.7) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs538962894, COSV65861402; called by muse, mutect2, varscan2
- EPPK1 | c.4344G>A p.V1448= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV101599999; called by muse, mutect2, varscan2
- EPS15L1 | c.2433C>T p.P811= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs1306081000, COSV50168155, COSV99933527; called by muse, mutect2, varscan2
- ERAP1 | c.1581G>A p.Q527= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57086918; called by muse, mutect2, varscan2
- ERAP2 | c.525C>T p.G175= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65939404; called by muse, mutect2, varscan2
- ESS2 | c.442C>T p.L148= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV52816713; called by muse, mutect2, varscan2
- FBXL13 | c.243C>T p.I81= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57536985; called by muse, mutect2
- FBXO21 | c.1413G>A p.L471= (on ENST00000330622 / NM_033624.3; = p.L464= on NM_015002.3) | Silent (SNP) | VAF 60/323 reads (19%) | catalogued as COSV100401639, COSV100401915; called by muse, mutect2, varscan2
- FGFR2 | c.990G>A p.R330= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV60644737; called by muse, mutect2, varscan2
- FKBP15 | c.3306C>T p.P1102= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs760552921, COSV53032432; called by muse, mutect2
- FMOD | c.27G>A p.L9= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs750237487, COSV100724659; called by muse, mutect2, varscan2
- FOXF2 | c.1182C>T p.P394= | Silent (SNP) | VAF 46/132 reads (35%) | catalogued as COSV52525511; called by muse, mutect2, varscan2
- FTCD | c.1407C>T p.A469= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV52424705; called by muse, mutect2, varscan2
- GABRB1 | c.1338G>A p.V446= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs79262532, COSV54977840; called by muse, mutect2, varscan2
- GALNT5 | c.2586C>T p.I862= | Silent (SNP) | VAF 45/183 reads (25%) | catalogued as COSV52037094; called by muse, mutect2, varscan2
- GBF1 | c.4242C>T p.L1414= (on ENST00000369983 / NM_001377137.1; = p.L1413= on NM_004193.3) | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV64144261; called by muse, mutect2, varscan2
- GDF5 | c.1332G>A p.T444= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs529197082, COSV65499041; called by muse, mutect2, varscan2
- GFRAL | c.651C>T p.P217= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV61230231; called by muse, mutect2, varscan2
- GIMAP6 | c.495G>A p.K165= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV61032728, COSV61033112; called by muse, mutect2
- GIMAP6 | c.141G>A p.G47= | Silent (SNP) | VAF 116/469 reads (25%) | catalogued as rs138777121, COSV61032937; called by muse, mutect2, varscan2
- GMIP | c.2568C>T p.L856= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs1038587018, COSV52555508; called by muse, mutect2, varscan2
- GPR137 | c.672C>T p.A224= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV100464643; called by muse, mutect2, varscan2
- GPRIN1 | c.717A>G p.R239= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as COSV56137241; called by muse, mutect2, varscan2
- GRAMD1B | c.1719C>T p.V573= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV59202948; called by muse, mutect2, varscan2
- GRIA2 | c.918G>A p.V306= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as rs1160382168, COSV52387783; called by muse, mutect2, varscan2
- H3-5 | c.42G>A p.G14= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1425416749, COSV100461779; called by muse, mutect2, varscan2
- HAND1 | c.579A>T p.P193= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV50562484; called by muse, mutect2, varscan2
- HEPACAM2 | c.1095C>T p.S365= (on ENST00000394468 / NM_001039372.4; = p.S353= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV59059609; called by muse, mutect2, varscan2
- HEPH | c.2211C>T p.I737= (on ENST00000343002; = p.I470= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV57961579, COSV57961986; called by muse, mutect2, varscan2
- HEPHL1 | c.2571A>G p.K857= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as rs1030697296, COSV59891211; called by muse, mutect2, varscan2
- HOXA9 | c.363C>T p.F121= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV58656035; called by muse, mutect2, varscan2
- HS1BP3 | c.946C>T p.L316= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV58312582, COSV58314262; called by muse, mutect2, varscan2
- HYDIN | c.13905G>A p.V4635= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- IFIT1 | c.1326C>T p.L442= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV65661330; called by muse, mutect2, varscan2
- IGHV1-2 | c.102G>A p.G34= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as rs538741365; called by muse, mutect2, varscan2
- IGSF21 | c.729G>A p.T243= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as rs371864848, COSV52137711; called by muse, mutect2, varscan2
- ITGA7 | c.2310C>T p.V770= (on ENST00000555728; = p.V726= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as COSV57694111; called by muse, mutect2, varscan2
- JUP | c.1836C>T p.A612= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV60277665; called by muse, mutect2
- KAT6A | c.618C>T p.I206= | Silent (SNP) | VAF 127/342 reads (37%) | catalogued as COSV55905193; called by muse, mutect2, varscan2
- KCNK1 | c.879C>T p.I293= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV64034905; called by muse, mutect2, varscan2
- KDM6B | c.2640G>A p.R880= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV54680318; called by muse, mutect2, varscan2
- KIAA1522 | c.1326C>T p.P442= (on ENST00000373480 / NM_001198972.2; = p.P501= on NM_020888.3) | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV53863668; called by muse, mutect2, varscan2
- KIF19 | c.597G>A p.L199= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as COSV63429260; called by muse, mutect2, varscan2
- KIF21B | c.4044C>T p.P1348= (on ENST00000422435 / NM_001252100.2; = p.P1335= on NM_017596.4) | Silent (SNP) | VAF 71/357 reads (20%) | catalogued as COSV59755938; called by muse, mutect2, varscan2
- KLK7 | c.288G>A p.S96= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs370063207, COSV58344140; called by muse, mutect2, varscan2
- KLK9 | c.219T>A p.L73= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV51591533; called by muse, mutect2
- KRT77 | c.228G>A p.G76= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV59239350; called by muse, mutect2, varscan2
- KSR2 | c.600G>A p.R200= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs199763793, COSV60373251; called by muse, mutect2
- LCT | c.552C>T p.H184= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as rs1186824359, COSV99919484; called by muse, mutect2, varscan2
- LIMK1 | c.969C>T p.S323= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV60280881; called by mutect2, varscan2
- LRP1 | c.1641C>T p.V547= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs1414356895, COSV54508086; called by muse, mutect2, varscan2
184 further variants in this file (0 protein-altering or splice-affecting, 173 silent, 11 other) are not listed here.
